Gene-level copy-number profile of tumor specimen TCGA-JY-A6FE-01A from TCGA case TCGA-JY-A6FE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 49.6 years (18,105 days).
Specimen TCGA-JY-A6FE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.286ed3fc-dbed-413b-8644-674d4c0d9528.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JY-A6FE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d47dbdc3-1209-491c-b882-a265f31e93e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 2,242; copy number 2: 36,135; copy number 3: 10,542; copy number 4: 7,533; copy number 5: 1,631; copy number 6: 1,201; copy number 7: 112; copy number 8: 125; copy number 10: 233.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JY-A6FE-01A-11D-A33D-01): tumor purity 0.71, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:54,874,605–54,901,255, 1 gene: CACNA2D3-AS1.
- chr9:14,475–215,893, 9 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1.
- chr13:48,389,567–48,444,704, 2 genes (within-gene range 0–5): LPAR6, Metazoa_SRP.
- chr14:61,529,128–61,658,696, 4 genes (within-gene range 0–3): AL355916.3, AL355916.2, LINC01303, AL355916.1.
- chr17:21,532,974–22,706,703, 40 genes: AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,268 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:7,758,714–10,054,936, 87 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).
- chr4:12,639,086–14,003,756, 17 genes, copy number 5–7 (within-gene range 4–7): ECM1P2, AC093809.1, AC007370.2, AC007370.1, U6, HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1, LINC01182, AC007126.1.
- chr4:16,360,686–18,021,876, 21 genes, copy number 5 (within-gene range 0–5): ZEB2P1, AC097515.1, LDB2, AC104656.1, AC106894.1, MTND5P4, LINC02493, SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, AC006160.2, LAP3, AC006160.1, MED28, FAM184B, DCAF16, NCAPG, LCORL, KRT18P63.
- chr4:22,594,196–22,819,575, 4 genes, copy number 6: AC098583.1, AC098583.2, GBA3, CDC42P6.
- chr4:23,560,923–33,011,746, 85 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–10 (broad region; genes not listed).
- chr6:167,607–2,786,952, 44 genes, copy number 5–6: AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1, AL359852.2, AL359852.1, LINC02521, LINC01600, MYLK4, WRNIP1.
- chr6:9,596,110–13,287,843, 63 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:13,521,266–13,814,568, 8 genes, copy number 7: RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1.
- chr6:24,544,104–24,705,065, 4 genes, copy number 6 (within-gene range 2–6): KIAA0319, KRT8P43, TDP2, ACOT13.
- chr6:48,701,491–57,222,307, 141 genes, copy number 6–7 (broad region; genes not listed).
- chr6:57,390,132–57,390,212, 1 gene, copy number 7: MIR548U.
- chr7:55,638,274–56,467,771, 45 genes, copy number 5–7: CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, AC006970.2, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P, SEPTIN14P24, CICP8, AC093392.2, RNU6-1052P, AC092423.1, AC092447.7, AC092447.10.
- chr8:31,275,542–39,284,917, 133 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr13:41,457,550–48,599,436, 134 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr13:48,488,963–61,199,880, 176 genes, copy number 5 (broad region; genes not listed).
- chr13:73,227,147–107,867,496, 395 genes, copy number 5–8 (broad region; genes not listed).
- chr13:107,870,383–107,873,372, 1 gene, copy number 8: AL136964.1.
- chr13:112,485,011–114,337,626, 60 genes, copy number 5: TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr16:35,169,692–35,912,516, 68 genes, copy number 5 (broad region; genes not listed).
- chr18:1,362,445–8,974,580, 131 genes, copy number 6 (broad region; genes not listed).
- chr19:58,326,994–58,605,223, 39 genes, copy number 6 (within-gene range 4–6): ZSCAN22, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1.
- chr20:8,077,251–8,968,360, 3 genes, copy number 5 (within-gene range 4–5): PLCB1, PHKBP1, PLCB1-IT1.
- chr20:30,278,906–64,313,132, 898 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,242. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
